CCDI case PBCRBY — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/58c88136-b11c-41fc-8bdc-5670f7049e9e

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Carcinomatosis: ICD-O-3 morphology code: 8010/9; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 16.1 years (5,871 days).

Biospecimens (3 samples)
- Sample 0DXJED: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DXJEY: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DXJGU: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
